Somatic mutation profile of tumor specimen TCGA-XR-A8TG-01A (aliquot TCGA-XR-A8TG-01A-11D-A35Z-10) from TCGA case TCGA-XR-A8TG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.0 years (21,544 days).
Specimen TCGA-XR-A8TG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a694b9ea-b465-4c1d-b2ec-f71d391b6d90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XR-A8TG-10A (Blood Derived Normal), aliquot TCGA-XR-A8TG-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67b71f72-aa1e-4587-a8e5-4a977e065b24

The open-access MAF lists 95 somatic variants for this specimen: 68 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 24, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 3, Frame Shift Del 2, 3'UTR 1, In Frame Del 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-2A>T p.X51_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | hotspot (GDC flag); catalogued as CS014762, CS127043, COSV58692638, COSV58692823, COSV58707376; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.3523A>G p.I1175V (on ENST00000614293; = p.I1145V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1166799567, COSV99687540; called by muse, mutect2, varscan2
- ACAA2 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99551820; called by muse, mutect2, varscan2
- AHNAK2 | c.7925C>T p.T2642I | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV100317368; called by muse, mutect2, varscan2
- ANK2 | c.4634C>G p.P1545R | Missense Mutation (SNP) | VAF 81/102 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100001427; called by muse, mutect2, varscan2
- ATP2B3 | c.1701A>C p.E567D | Missense Mutation (SNP) | VAF 75/86 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV99684273; called by muse, mutect2, varscan2
- ATRNL1 | c.3265C>T p.Q1089* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100370470, COSV58111217; called by muse, mutect2, varscan2
- BIRC6 | c.5129C>G p.T1710S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1456012932, COSV101428249; called by muse, mutect2, varscan2
- BVES | c.746T>G p.F249C | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100114902; called by muse, mutect2, varscan2
- C16orf71 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs765201393, COSV100172919; called by muse, mutect2, varscan2
- CEP350 | c.3597G>C p.E1199D | Missense Mutation (SNP) | VAF 291/529 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100854608; called by muse, mutect2, varscan2
- CES1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 132/320 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV100828663; called by muse, mutect2, varscan2
- CHD1 | c.4801A>T p.R1601* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | catalogued as COSV99399400; called by muse, mutect2, varscan2
- CILP2 | c.1334G>T p.R445I | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99364646; called by muse, mutect2
- CITED2 | c.294C>A p.F98L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs772009858, COSV100863108; called by muse, mutect2, varscan2
- DNAH8 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 171/466 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100544994, COSV59443534; called by muse, mutect2, varscan2
- DYNC2H1 | c.4872G>T p.W1624C | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518442; called by muse, mutect2, varscan2
- FAAH | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV99680049; called by muse, mutect2, varscan2
- FILIP1 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1394740851, COSV99384689; called by muse, mutect2, varscan2
- FLT3LG | c.676A>T p.S226C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99201302; called by muse, mutect2, varscan2
- FRK | c.89A>G p.E30G | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101661767; called by muse, mutect2, varscan2
- GAB2 | c.809G>A p.R270H (on ENST00000361507 / NM_080491.3; = p.R232H on NM_012296.3) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs1333354447, COSV100416468; called by muse, mutect2
- GRB14 | c.1453dup p.I485Nfs*12 | Frame Shift Ins (INS) | VAF 47/293 reads (16%) | catalogued as rs776664771; called by mutect2, pindel, varscan2
- GRM1 | c.3169G>T p.G1057C | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.275); catalogued as COSV99265960; called by muse, mutect2, varscan2
- GYS2 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as rs1474338509, COSV99679727; called by muse, mutect2, varscan2
- HAUS2 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as COSV99535374; called by muse, mutect2, varscan2
- IGFBP3 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99298325; called by muse, mutect2, varscan2
- IL18RAP | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51827586; called by muse, mutect2, varscan2
- ITGB4 | c.2930G>T p.R977L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99563962; called by muse, mutect2, varscan2
- JPH1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100646576; called by muse, mutect2, varscan2
- KIAA0408 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs1274434596, COSV100846903; called by muse, mutect2, varscan2
- KRT6A | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58107815; called by muse, mutect2, varscan2
- LARP1B | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99218179; called by muse, mutect2, varscan2
- LSM10 | c.134A>T p.N45I | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100240024; called by muse, mutect2, varscan2
- MAP3K21 | c.2037G>T p.Q679H | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV100786100; called by muse, mutect2
- MICALL2 | c.998A>T p.E333V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs761675494, COSV99875904; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO18B | c.4874G>A p.G1625D | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.068); catalogued as COSV100123516; called by muse, mutect2, varscan2
- OAS3 | c.2707T>C p.S903P | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.596); catalogued as rs777228469, COSV99966251; called by muse, mutect2, varscan2
- OR8B4 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100635813; called by muse, mutect2, varscan2
- PACSIN1 | c.35C>A p.P12Q | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99763066; called by muse, mutect2, varscan2
- PCBP1 | c.1038G>T p.R346S | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100340147; called by muse, mutect2, varscan2
- PCMTD1 | c.952A>C p.K318Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV100859642; called by muse, mutect2, varscan2
- PDZD9 | c.602A>G p.D201G (on ENST00000424898 / NM_001363519.1; = p.D141G on NM_173806.4) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV51674423; called by muse, mutect2, varscan2
- PEX5L | c.93+1G>A p.X31_splice | Splice Site (SNP) | VAF 28/73 reads (38%) | catalogued as rs1352027438, COSV99828584; called by muse, mutect2, varscan2
- PKHD1L1 | c.12536C>T p.S4179F | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV101006044; called by muse, mutect2
- PNMA8A | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs116822170, COSV58138102, COSV58139624; called by muse, mutect2, varscan2
- PREX2 | c.4534T>C p.S1512P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV99906959; called by muse, mutect2, varscan2
- PRMT3 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100423893, COSV58179607; called by muse, mutect2, varscan2
- SDK1 | c.3359C>T p.T1120I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1365111979, COSV101269345; called by muse, mutect2, varscan2
- SHD | c.797T>G p.L266R | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100010248; called by muse, mutect2, varscan2
- TDG | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 32/150 reads (21%) | catalogued as COSV99904156; called by muse, mutect2
- TENM2 | c.1805G>C p.C602S (on ENST00000518659 / NM_001122679.2; = p.C370S on NM_001080428.3) | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101318609; called by muse, mutect2, varscan2
- TMEM132B | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs149523266, COSV54743295; called by muse, mutect2, varscan2
- TP53 | c.994A>T p.I332F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52849382, COSV53175834, COSV99400287; called by muse, mutect2, varscan2
- TPR | c.2181G>T p.M727I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.097); catalogued as COSV100823892; called by muse, mutect2, varscan2
- USH1C | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV50015014, COSV99139922; called by muse, mutect2, varscan2
- VPS4B | c.485-1G>T p.X162_splice | Splice Site (SNP) | VAF 30/101 reads (30%) | catalogued as COSV99447921; called by muse, mutect2, varscan2
- VSX2 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 32/367 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs770384606, COSV100001598; called by muse, mutect2
- YTHDC1 | c.2132G>T p.R711L (on ENST00000344157 / NM_001031732.4; = p.R693L on NM_133370.4) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV60011360; called by muse, mutect2, varscan2
- ZC3H12A | c.482T>A p.L161Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.262); catalogued as COSV100897703; called by muse, mutect2, varscan2
- ZNF43 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV100731803; called by muse, mutect2, varscan2
- ZNF827 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs139372039, COSV101061317; called by muse, mutect2, varscan2
- AGA | c.744del p.D248Efs*16 | Frame Shift Del (DEL) | VAF 104/370 reads (28%) | called by mutect2, pindel, varscan2
- CRH | c.350_364del p.Q117_L121del | In Frame Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- LCAT | c.546_547insGG p.K183Gfs*82 | Frame Shift Ins (INS) | VAF 46/140 reads (33%) | called by mutect2, pindel*, varscan2
- SRSF11 | c.1317dup p.E440Rfs*12 | Frame Shift Ins (INS) | VAF 78/236 reads (33%) | called by mutect2, pindel, varscan2
- ADD1 | c.1443C>A p.S481= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as COSV99296401; called by muse, mutect2, varscan2
- AGTPBP1 | c.3567A>G p.A1189= (on ENST00000357081 / NM_001330701.2; = p.A1149= on NM_015239.2) | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV100429693; called by muse, mutect2, varscan2
- AHNAK | c.9831A>G p.K3277= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV99945650; called by muse, mutect2, varscan2
- BEND5 | c.891C>A p.G297= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as rs1216967585, COSV65717235; called by muse, mutect2
- CD300E | c.384C>T p.S128= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs758148094, COSV100151272; called by muse, mutect2, varscan2
- CSMD1 | c.3012G>T p.V1004= (on ENST00000520002; = p.V1003= on NM_033225.6) | Silent (SNP) | VAF 60/77 reads (78%) | catalogued as COSV100147238; called by muse, mutect2, varscan2
- DMD | c.4215A>G p.Q1405= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100819518; called by muse, mutect2, varscan2
- EHD3 | c.483G>A p.E161= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV100434708; called by muse, mutect2, varscan2
- EML1 | c.1897C>A p.R633= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV99214946; called by muse, mutect2, varscan2
- FLG2 | c.2247G>C p.G749= | Silent (SNP) | VAF 100/197 reads (51%) | catalogued as COSV101165831; called by muse, mutect2, varscan2
- GDF2 | c.144G>A p.L48= | Silent (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- GSTM3 | c.423A>G p.Q141= | Silent (SNP) | VAF 102/251 reads (41%) | catalogued as rs1271674725, COSV99860203; called by muse, mutect2, varscan2
- HOXD12 | c.78C>T p.F26= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs758678753, COSV101184261; called by muse, mutect2, varscan2
- KRT38 | c.1098C>T p.I366= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99878204; called by muse, mutect2, varscan2
- OPHN1 | c.720C>A p.S240= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100830399; called by muse, mutect2
- OR4S2 | c.468C>A p.I156= | Silent (SNP) | VAF 74/165 reads (45%) | catalogued as COSV100412636, COSV56747003; called by muse, mutect2, varscan2
- OR6K6 | c.228C>T p.V76= (on ENST00000368144; = p.V52= on NM_001005184.1) | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as COSV100933738; called by muse, mutect2, varscan2
- PSMG1 | c.690A>G p.A230= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100521897; called by muse, mutect2, varscan2
- SIGLEC11 | c.210T>C p.Y70= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as rs764599629, COSV101389327; called by muse, mutect2, varscan2
- SLAIN2 | c.1254C>A p.S418= | Silent (SNP) | VAF 21/482 reads (4%) | catalogued as COSV99971630; called by muse, mutect2
- SMG8 | c.1746A>G p.S582= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99958812; called by mutect2, varscan2
- SSR2 | c.333T>G p.T111= | Silent (SNP) | VAF 49/243 reads (20%) | catalogued as COSV99828582; called by muse, mutect2, varscan2
- TENM3 | c.7842C>T p.D2614= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs772839377, COSV101305085, COSV69316839; called by muse, mutect2, varscan2
- TNXB | c.4926C>T p.P1642= (on ENST00000647633; = p.P1395= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100926260; called by muse, mutect2, varscan2
- DDHD1 | chr14:53152702 C>T | 5'Flank (SNP) | VAF 4/74 reads (5%) | catalogued as rs1411931105, COSV100079485; called by muse, mutect2
- RASSF10 | c.-164G>A | 5'UTR (SNP) | VAF 20/49 reads (41%) | catalogued as rs759268323; called by muse, mutect2, varscan2
- ZNRF2 | c.*2C>T | 3'UTR (SNP) | VAF 57/494 reads (12%) | catalogued as COSV100546171; called by muse, mutect2, varscan2
